Gene-level copy-number profile of tumor specimen TCGA-FW-A3I3-06A from TCGA case TCGA-FW-A3I3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 59.5 years (21,731 days).
Specimen TCGA-FW-A3I3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.b862d5c8-e18c-43a6-8869-a7d4289ac740.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FW-A3I3-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f9f40220-2247-4fdb-95c8-dc3e6883f31c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 179; copy number 2: 15,802; copy number 3: 18,016; copy number 4: 17,093; copy number 5: 7,857; copy number 6: 224; copy number 7: 249; copy number 8: 178; copy number 9: 34; copy number 10: 88; copy number 11: 43; copy number 12: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FW-A3I3-06A-11D-A219-01): tumor purity 0.89, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,449,745–141,615,344, 5 genes (within-gene range 0–3): AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6.
- chr9:21,695,176–22,214,672, 17 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:130,400,266–130,638,352, 4 genes (within-gene range 0–2): RN7SL665P, ASS1, FUBP3, MIR6856.
- chr11:98,938,912–98,945,079, 1 gene: AP002428.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 612 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:44,495,099–51,410,205, 31 genes, copy number 7 (within-gene range 4–7): LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47.
- chr5:51,963,992–56,976,224, 101 genes, copy number 7 (broad region; genes not listed).
- chr5:60,945,177–62,146,946, 17 genes, copy number 7 (within-gene range 6–7): NDUFAF2, AC008498.2, AC008498.1, SMIM15, SMIM15-AS1, LINC02057, ZSWIM6, AC122718.2, AC122718.1, RPL3P6, C5orf64, AC026746.1, RNU6-913P, C5orf64-AS1, AC026434.1, AC008877.1, RN7SKP157.
- chr5:64,506,015–67,169,595, 39 genes, copy number 7 (within-gene range 3–7): RGS7BP, RN7SL169P, RNU6-294P, MRPL49P1, SHISAL2B, SREK1IP1, CWC27, AC092354.2, AC092354.1, Y_RNA, ADAMTS6, AC008868.1, RPEP1, AC025186.1, AC025176.1, CENPK, PPWD1, TRIM23, RNU6-540P, TRAPPC13, SHLD3, SGTB, NLN, AC008958.1, AC010359.2, ERBIN, AC010359.1, AC010359.3, AC025442.2, SREK1, AC025442.1, LINC02065, AC092353.1, AC092353.2, LINC02229, PPIAP78, MAST4, AC092349.1, MAST4-IT1.
- chr5:68,087,161–68,434,481, 7 genes, copy number 8: AC010376.1, RNU6-1232P, EEF1B2P2, LINC02219, PIK3R1, AC024579.1, AC010280.2.
- chr5:71,754,378–93,091,768, 344 genes, copy number 7–12 (broad region; genes not listed).
- chr5:94,152,966–94,739,436, 7 genes, copy number 7 (within-gene range 3–9): KIAA0825, MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1.
- chr5:97,504,663–98,681,367, 16 genes, copy number 8: LINC01340, MTCYBP40, AC112203.1, AC122697.1, LINC02234, AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4.
- chr5:103,408,941–103,562,790, 4 genes, copy number 8: AC010406.1, PDZPH1P, LINC02115, NUDT12.
- chr5:106,415,576–106,546,803, 3 genes, copy number 7: AC027313.1, AC114940.1, AC114940.2.
- chr5:107,195,156–107,670,937, 2 genes, copy number 8 (within-gene range 3–8): PSMC1P5, EFNA5.
- chr5:164,296,696–165,171,643, 1 gene, copy number 10 (within-gene range 3–10): AC109466.1.
- chr5:164,935,162–166,155,439, 9 genes, copy number 8–10: RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1.
- chr5:166,905,222–167,168,401, 3 genes, copy number 8: LINC01947, AC091819.2, AC091819.1.
- chr5:167,287,320–167,660,481, 4 genes, copy number 8: AC091820.2, AC091820.1, AC008601.1, AC008708.2.
- chr6:5,817,421–6,007,605, 5 genes, copy number 7: AL136968.1, AL136307.1, RN7SL221P, PKMP5, NRN1.
- chr19:33,299,934–34,093,310, 19 genes, copy number 7: AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21.

Autosomal genes at a single copy (total copy number 1): 128. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
